Somatic mutation profile of tumor specimen TCGA-KS-A4I9-01A (aliquot TCGA-KS-A4I9-01A-11D-A257-08) from TCGA case TCGA-KS-A4I9, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 46.4 years (16,961 days).
Specimen TCGA-KS-A4I9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e3d8f688-e916-478e-82ee-21d34d93f303.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KS-A4I9-11A (Solid Tissue Normal), aliquot TCGA-KS-A4I9-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c42dfaac-feb9-415b-891b-43c1a509f165

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 7, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FBLN1 | c.1832G>A p.R611H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs771580675, COSV59936686; called by muse, mutect2, varscan2
- KRT33B | c.348+1G>T p.X116_splice | Splice Site (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99290726; called by muse, mutect2, varscan2
- SLCO4C1 | c.832C>G p.P278A | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV60513724; called by muse, mutect2, varscan2
- SMURF2 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52313515; called by muse, mutect2, varscan2
- STAR | c.263G>A p.G88D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV52417063; called by muse, mutect2, varscan2
- STARD3 | c.79T>G p.S27A | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV60419398; called by muse, mutect2, varscan2
- ZFP41 | c.165A>C p.E55D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.112); catalogued as COSV58086404; called by muse, mutect2, varscan2
